Somatic mutation profile of tumor specimen ALCH-B3DE-TTP1-A (aliquot ALCH-B3DE-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3DE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,294 days).
Specimen ALCH-B3DE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7737c9a3-4d1c-4cab-9296-3c986c14d888.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DE-NB1-A (Blood Derived Normal), aliquot ALCH-B3DE-NB1-A-2-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae9ef91f-770d-44a2-b1be-49adc72947d6

The open-access MAF lists 80 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 15, Nonsense Mutation 4, Intron 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 44/572 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- BNC2 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 24/874 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1362121192, COSV66143271; called by muse, mutect2
- C10orf71 | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.073); catalogued as rs1361840536; called by muse, mutect2
- CRTAM | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1214209894, COSV57067966; called by muse, mutect2
- CSMD3 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 23/834 reads (3%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1564168791, COSV52105622, COSV52155991; called by muse, mutect2
- DNAJC25 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 7/183 reads (4%) | catalogued as COSV57957002; called by muse, mutect2
- FLG2 | c.3775C>A p.Q1259K | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as COSV66166534; called by muse, mutect2
- NYNRIN | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs1395057616; called by muse, mutect2
- OR2T6 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100861477; called by muse, mutect2
- PCDHB5 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 33/1150 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782550910, COSV50652564, COSV99167683; called by muse, mutect2
- PPID | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 16/581 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs1229416573; called by muse, mutect2
- RYR2 | c.13840G>T p.G4614W | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936573890, COSV100769562, COSV63672474; called by muse, mutect2
- SIGLEC12 | c.952G>T p.D318Y (on ENST00000291707 / NM_053003.4; = p.D200Y on NM_033329.2) | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs1203135034; called by muse, mutect2
- SLC16A2 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 34/847 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.959); catalogued as rs1489135756, COSV52085104; called by muse, mutect2
- SLITRK4 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 26/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022494; called by muse, mutect2
- ST18 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs763259250; called by muse, mutect2
- TCHHL1 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 14/423 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV64285596; called by muse, mutect2
- TMCC2 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63665754; called by muse, mutect2
- ABI1 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 14/479 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- ACTRT1 | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- APBA3 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- AR | c.1526T>A p.V509E | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- ARHGEF9 | c.925-1G>A p.X309_splice | Splice Site (SNP) | VAF 23/493 reads (5%) | called by muse, mutect2
- CDH1 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 20/688 reads (3%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.49); called by muse, mutect2
- CLMN | c.1925G>C p.C642S | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP4 | c.2482G>T p.G828W | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL10A1 | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2
- FAM155B | c.1005C>G p.Y335* | Nonsense Mutation (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- FAT3 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2
- GALNT2 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GLO1 | c.340A>C p.S114R | Missense Mutation (SNP) | VAF 28/441 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.288); called by muse, mutect2
- GLUD1 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLUD2 | c.594G>T p.L198F | Missense Mutation (SNP) | VAF 20/694 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HEPACAM2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 19/639 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.116); called by muse, mutect2
- IGKV2D-24 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 25/902 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.191); called by muse, mutect2
- INTS10 | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- INTS8 | c.2371A>G p.I791V | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- KRT17 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 23/535 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); called by muse, mutect2
- LGR5 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.3); called by muse, mutect2
- LRP1B | c.7839C>A p.N2613K | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- MROH2B | c.1879C>A p.Q627K | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.197); called by muse, mutect2
- MTRF1L | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); called by muse, mutect2
- NLK | c.1354A>C p.T452P | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2
- OR14K1 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- OR2H1 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- OR5T1 | c.533T>A p.L178Q | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCL1 | c.1936G>C p.A646P | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- POF1B | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 34/916 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2
- POLI | c.1636G>T p.G546* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- POU5F1 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 34/594 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2
- RANBP1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- RYR2 | c.7419C>A p.D2473E | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.261); called by muse, mutect2
- RYR2 | c.11492A>T p.Q3831L | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.681); called by muse, mutect2
- SCN5A | c.5465C>G p.S1822C (on ENST00000333535 / NM_198056.3; = p.S1821C on NM_000335.5) | Missense Mutation (SNP) | VAF 26/872 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- SGK3 | c.551A>T p.D184V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2
- SI | c.3968G>T p.W1323L | Missense Mutation (SNP) | VAF 15/381 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); called by muse, mutect2
- SLC6A8 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 49/553 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX13C | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.393); called by muse, mutect2
- TLR4 | c.1126G>T p.E376* (on ENST00000355622 / NM_138554.5; = p.E336* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- TNFAIP2 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2
- TOM1L2 | c.607C>T p.P203S (on ENST00000379504 / NM_001350333.2; = p.P153S on NM_001033551.3) | Missense Mutation (SNP) | VAF 15/483 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.069); called by muse, mutect2
- ZNF488 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- B4GALT4 | c.442C>T p.L148= | Silent (SNP) | VAF 27/473 reads (6%) | called by muse, mutect2
- CDRT15L2 | c.636G>T p.L212= | Silent (SNP) | VAF 15/286 reads (5%) | called by muse, mutect2
- CORO2B | c.1356G>A p.L452= | Silent (SNP) | VAF 22/538 reads (4%) | called by muse, mutect2
- DNA2 | c.1311C>T p.H437= | Silent (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- FGD6 | c.1194C>T p.V398= | Silent (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- FUOM | c.333G>T p.L111= | Silent (SNP) | VAF 13/400 reads (3%) | catalogued as rs1362295922; called by muse, mutect2
- GBP7 | c.258C>A p.P86= | Silent (SNP) | VAF 24/800 reads (3%) | called by muse, mutect2
- ITGA2 | c.57C>T p.L19= | Silent (SNP) | VAF 20/380 reads (5%) | called by muse, mutect2
- NINJ1 | c.30C>G p.L10= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- PCDHA8 | c.1743G>T p.V581= | Silent (SNP) | VAF 21/513 reads (4%) | catalogued as rs781925057, COSV65329381; called by muse, mutect2
- PHLDB3 | c.1482C>T p.I494= | Silent (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- SPATA6 | c.1323T>C p.D441= | Silent (SNP) | VAF 9/272 reads (3%) | called by muse, mutect2
- STATH | c.183C>A p.T61= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- TCHHL1 | c.1131T>A p.G377= | Silent (SNP) | VAF 32/472 reads (7%) | called by muse, mutect2
- TGM2 | c.2040G>C p.R680= | Silent (SNP) | VAF 18/507 reads (4%) | called by muse, mutect2
- GUSBP1 | n.180-4580G>T | Intron (SNP) | VAF 34/883 reads (4%) | called by muse, mutect2
- NBPF11 | c.-548-3228G>T | Intron (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- RPS6KA1 | c.109-946G>T | Intron (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
